Surgical pathology report (de-identified scan), TCGA case TCGA-G7-6795, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site Roswell Park, specimen TCGA-G7-6795-01A (Primary Tumor).

[page 1 of 2]
SPECIMENS:

A. LEFT KIDNEY

SPECIMEN(S):

A. LEFT KIDNEY

GROSS DESCRIPTION:

A. LEFT KIDNEY, NEPHRECTOMY:

Received fresh state a specimen labelled with patient's name and identification number as above, and labelled "LEFT KIDNEY". Specimen consists of a left radical nephrectomy specimen comprised of left kidney with abundant perinephric fat, attached ureter and left adrenal gland with a combined weight of 1400 grams. The specimen measures 21 x 13 x 11.5 cm. The attached ureter measures 3 cm. in length and 1 cm. in diameter. Adrenal gland measures 3 x 2.5 x 1.5 cm. grossly is not remarkable. Mucosa of ureter, and hilar blood vessels are not remarkable. The specimen when bisected, located along the upper pole is a 2.5 x 2.5 x 1.8 cm. solid mass with creamy yellowish cut surface. Grossly the tumor appears confined within kidney parenchyma. The cortex shows distortion by various size cysts and marked fatty infiltration of medullary area. Cysts ranging in size from 0.2 cm to 2.5 cm. Some cysts display golden-yellow discoloration around the gray-tan lining. The perirenal fat is difficult to separate from the renal capsule. Multiple sections are submitted in cassettes labelled as follows:

- A1: ureteral and vascular margins
- A2-A6: sections from tumor in toto
- A7-A13: sections from cyst
- A14: sections from adrenal gland
- A15-A16: presumptive lymph nodes

DIAGNOSIS:

A. LEFT KIDNEY, NEPHRECTOMY:

- PAPILLARY RENAL CELL CARCINOMA, FUHRMAN GRADE 2 OF LEFT KIDNEY.
- SIZE OF TUMOR – 2.5 X 2.5 X 1.8 CM.
- CHRONIC INTERSTITIAL PYELONEPHRITIS WITH PROMINENT CYSTIC CHANGES..
- LEFT ADRENAL GLAND – NO SPECIFIC PATHOLOGIC CHANGE –
NEGATIVE FOR TUMOR.
- URETERAL AND HILAR VASCULAR MARGINS– NEGATIVE
FOR TUMOR.

SYNOPTIC REPORT - KIDNEY (PARTIAL OR RADICAL)

Specimens Involved

Specimens: A: LEFT KIDNEY

Specimen Type: Radical nephrectomy

With adrenal gland

Laterality: Left

Tumor Site: Upper pole

Focality: Unifocal

Tumor Size (largest tumor if multiple): Greatest dimension: 2.5cm

Additional dimensions: 2.5cm x 1.8cm

Macroscopic Extent of Tumor: Tumor limited to kidney

WHO CLASSIFICATION

Papillary renal cell carcinoma 8260/3

Histologic Grade (Fuhrman Nuclear Grade): G2: Nuclei slightly irregular, approximately 15 µ; nucleoli evident

Invasion of Vascular/Lymphatic: Absent

Perinephric Tissue Invasion: Absent

Margins: Margins uninvolved by invasive carcinoma

Adrenal Gland: Uninvolved by tumor

Regional Lymph Nodes: Negative 0 / 2

Additional Findings: Interstitial disease

type:: chronic interstitial pyelonephritis cystic changes

[page 2 of 2]
Pathological Staging (pTNM): pT 1a N 0 M x

CLINICAL HISTORY:

None given

PRE-OPERATIVE DIAGNOSIS:

Left renal mass

Source: NCI Genomic Data Commons file d96116c2-da3b-4c32-a339-a49c3cad0372 (TCGA-G7-6795.CB1A128F-068C-4C27-88B6-CA9C90EE9EE8.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).